Somatic mutation profile of tumor specimen TCGA-VS-A8EL-01A (aliquot TCGA-VS-A8EL-01A-11D-A37N-09) from TCGA case TCGA-VS-A8EL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 38.8 years (14,162 days).
Specimen TCGA-VS-A8EL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea41e12c-e564-4564-878a-d4dfe4fa6130.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A8EL-10A (Blood Derived Normal), aliquot TCGA-VS-A8EL-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81807044-25b6-4ff2-8347-6d56e3be606a

The open-access MAF lists 366 somatic variants for this specimen: 267 protein-altering or splice-affecting, 93 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 246, Silent 93, Nonsense Mutation 16, Intron 4, Frame Shift Del 3, 5'UTR 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHDC1 | c.2380C>T p.Q794* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | catalogued as rs1553158947, COSV99899797; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PDHA1 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs794729213, CM000553, CM013279, COSV63328534; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC109583.1 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100167992; called by muse, mutect2, varscan2
- ACACB | c.6925G>C p.E2309Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); catalogued as COSV100623344; called by muse, mutect2, varscan2
- ACAP2 | c.360C>G p.F120L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.354); catalogued as COSV100462810; called by muse, mutect2
- ACLY | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1555628085, COSV100709930; called by muse, mutect2, varscan2
- ACO1 | c.1051C>G p.Q351E | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as COSV100008720; called by muse, mutect2, varscan2
- ADAMTS12 | c.4335G>C p.E1445D | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV100711740; called by muse, mutect2, varscan2
- ADAMTS14 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs777171630, COSV100941906; called by muse, mutect2, varscan2
- ADAMTS3 | c.1418G>A p.G473E | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99712227; called by muse, mutect2, varscan2
- ADGRL2 | c.571G>C p.D191H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99591831; called by muse, mutect2, varscan2
- ADPRHL1 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.519); catalogued as COSV100733585; called by muse, mutect2, varscan2
- ADRM1 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.887); catalogued as rs369505590; called by muse, mutect2, varscan2
- AGBL1 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV101224357; called by muse, mutect2, varscan2
- AHCTF1 | c.1361G>A p.G454E (on ENST00000366508; = p.G428E on NM_015446.5) | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.536); catalogued as COSV58253971; called by muse, mutect2, varscan2
- AHNAK2 | c.17158G>C p.E5720Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.573); catalogued as COSV100319132, COSV60933378; called by muse, mutect2, varscan2
- AKAP12 | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs1398992703, COSV99484542; called by muse, mutect2, varscan2
- ANAPC1 | c.1597G>C p.D533H | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.286); catalogued as COSV100595142; called by muse, mutect2, varscan2
- ANKRD11 | c.5794G>C p.E1932Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV99970775; called by muse, mutect2, varscan2
- ANP32A | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as COSV99143081; called by muse, mutect2, varscan2
- ANXA6 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.185); catalogued as rs1267534277, COSV100637126; called by muse, mutect2, varscan2
- ANXA7 | c.784G>A p.D262N (on ENST00000372919 / NM_001320880.2; = p.D240N on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769213073, COSV100873523; called by muse, mutect2, varscan2
- ARHGEF10L | c.3425G>T p.R1142L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.152); catalogued as rs147651088; called by muse, mutect2, varscan2
- ARID1A | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100253681, COSV61382958; called by muse, mutect2, varscan2
- ASIC3 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.116); catalogued as COSV52506817, COSV99874856; called by muse, mutect2, varscan2
- ATP1A2 | c.2716G>A p.E906K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.841); catalogued as COSV100768195; called by muse, mutect2, varscan2
- ATRX | c.1787C>T p.S596F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as COSV100971541; called by muse, mutect2, varscan2
- B4GALT3 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.781); catalogued as rs756962425, COSV60526693; called by muse, mutect2, varscan2
- BAZ2A | c.2218C>T p.Q740* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99467898; called by muse, mutect2, varscan2
- BBS2 | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746505864, CM101917, COSV99802894; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BNIP3 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as COSV100893311; called by muse, mutect2
- BPTF | c.4074G>T p.K1358N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.022); catalogued as COSV100076059, COSV100076176; called by muse, mutect2, varscan2
- BRMS1L | c.563C>G p.S188* | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | catalogued as COSV99396860; called by muse, mutect2, varscan2
- BRMS1L | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1045749864, COSV99396862; called by muse, mutect2, varscan2
- C11orf42 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV99792574; called by muse, mutect2, varscan2
- C19orf54 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV99649115; called by muse, mutect2, varscan2
- C3orf38 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV100007505; called by muse, mutect2, varscan2
- CACNA1H | c.4205G>A p.R1402Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1192663419, COSV100670705; called by muse, mutect2, varscan2
- CALHM2 | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.357); catalogued as COSV99588839; called by muse, mutect2, varscan2
- CARMIL1 | c.3499C>A p.L1167M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100276839; called by muse, mutect2, varscan2
- CASP8 | c.1015C>T p.Q339* (on ENST00000432109 / NM_033355.3; = p.Q356* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV51852083; called by muse, mutect2, varscan2
- CASP9 | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100423993; called by muse, mutect2, varscan2
- CASR | c.2638C>G p.Q880E (on ENST00000490131; = p.Q957E on NM_000388.4) | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.022); catalogued as COSV99949529; called by muse, mutect2, varscan2
- CCDC114 | c.1669C>T p.L557F | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs748321185, COSV100197159; called by muse, mutect2, varscan2
- CCDC178 | c.2182G>A p.D728N (on ENST00000383096 / NM_001105528.3; = p.D690N on NM_198995.3) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs528805719, COSV100287048; called by muse, mutect2, varscan2
- CCDC191 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99878825; called by muse, mutect2
- CCM2L | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99395502; called by muse, mutect2, varscan2
- CCNC | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100412714; called by muse, mutect2, varscan2
- CCNC | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV100412717; called by muse, mutect2, varscan2
- CCNL1 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as rs749964157, COSV55819015; called by muse, mutect2, varscan2
- CCNL2 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101275749; called by muse, mutect2, varscan2
- CCSER2 | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV99826599; called by muse, mutect2, varscan2
- CEACAM6 | c.215G>C p.R72T | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as COSV99555785; called by muse, mutect2, varscan2
- CFAP74 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.007); catalogued as COSV99574821; called by muse, mutect2, varscan2
- CHD4 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.217); catalogued as rs1266176133, COSV100539366, COSV58908718; called by muse, mutect2, varscan2
- CHD8 | c.2842G>C p.D948H (on ENST00000646647 / NM_001170629.2; = p.D669H on NM_020920.4) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101303224; called by muse, mutect2, varscan2
- CHEK2 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); catalogued as COSV60425918; called by muse, mutect2, varscan2
- CHRNA5 | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100214065; called by muse, mutect2, varscan2
- CHURC1 | c.295G>A p.E99K (on ENST00000549115 / NM_001204063.1; = p.E100K on NM_145165.3) | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV100767499; called by muse, mutect2, varscan2
- CLDN18 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs768414784, COSV51738820; called by muse, mutect2, varscan2
- CLUH | c.2725G>T p.D909Y (on ENST00000435359; = p.D948Y on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as rs374551796, COSV101425915; called by muse, mutect2
- CUX2 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs199740303; called by muse, mutect2, varscan2
- CXCR5 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.015); catalogued as rs141581349; called by muse, mutect2, varscan2
- CYRIA | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100838594; called by muse, mutect2, varscan2
- D2HGDH | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs142050154, CM101378, COSV58323824; called by muse, mutect2, varscan2
- DACH1 | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); catalogued as rs1270054158, COSV100499399; called by muse, mutect2, varscan2
- DARS2 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.241); catalogued as COSV99508939; called by muse, mutect2, varscan2
- DCAF16 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV101200483; called by muse, mutect2, varscan2
- DLG2 | c.120C>G p.I40M (on ENST00000650630 / NM_001351274.2; = p.I3M on NM_001142699.3) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65888144; called by muse, mutect2, varscan2
- DNAH9 | c.9691G>A p.E3231K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as COSV99308463; called by muse, mutect2
- DOLK | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV100455295; called by muse, varscan2
- DOLK | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as rs981981444, COSV100455296; called by muse, varscan2
- DOP1A | c.5902C>T p.Q1968* | Nonsense Mutation (SNP) | VAF 27/92 reads (29%) | catalogued as COSV99383044; called by muse, mutect2, varscan2
- DPP6 | c.338C>T p.S113L (on ENST00000377770 / NM_001364500.2; = p.S51L on NM_001936.5) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774135792, COSV100128464; called by muse, mutect2, varscan2
- DYNC1LI2 | c.1051G>C p.D351H | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99263293; called by muse, mutect2, varscan2
- ECD | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV61969875; called by muse, mutect2, varscan2
- EDC3 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.604); catalogued as rs772170307, COSV100166196; called by muse, mutect2, varscan2
- EIF4A1 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV99549279; called by muse, mutect2
- ELAVL4 | c.726G>C p.Q242H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV100836940; called by muse, mutect2, varscan2
- ENTPD6 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.463); catalogued as COSV100737195, COSV61751798; called by muse, mutect2, varscan2
- EPHA2 | c.1987G>C p.E663Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100626325, COSV64452197, COSV64452207; called by muse, mutect2, varscan2
- EPHA2 | c.1806G>C p.L602F | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV100626326, COSV64452184; called by muse, mutect2, varscan2
- EVI5L | c.1426G>A p.G476R | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.323); catalogued as COSV99563614; called by muse, mutect2, varscan2
- EXOC4 | c.1804G>C p.D602H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV99555977; called by muse, mutect2, varscan2
- EXOC6B | c.1535C>T p.S512L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV99726719; called by muse, mutect2, varscan2
- EXOSC10 | c.1162G>C p.D388H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1168284020, COSV100442962; called by muse, mutect2, varscan2
- FAM107B | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.127); catalogued as COSV99474514; called by muse, mutect2, varscan2
- FAM135B | c.1132G>C p.D378H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV99428206; called by muse, mutect2, varscan2
- FAM47B | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV100264682; called by muse, mutect2
- FBXO10 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99447349; called by muse, mutect2, varscan2
- FGF20 | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs1328283813, COSV99471675; called by muse, mutect2, varscan2
- FMNL1 | c.604C>A p.L202M | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.287); catalogued as COSV100057028; called by muse, mutect2, varscan2
- FMNL2 | c.2956G>A p.E986K | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.159); catalogued as COSV99981039; called by muse, mutect2
- FOXC2 | c.66G>C p.Q22H | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100234420, COSV57445238; called by muse, mutect2, varscan2
- FREM1 | c.782C>G p.S261C | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs1258532676, COSV101085602; called by muse, mutect2, varscan2
- GAPVD1 | c.1790C>G p.S597* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99783585, COSV99783872; called by muse, mutect2, varscan2
- GFPT1 | c.1930G>A p.E644K (on ENST00000357308 / NM_001244710.2; = p.E626K on NM_002056.4) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.144); catalogued as COSV100622709, COSV100623013; called by muse, mutect2, varscan2
- GPAT4 | c.1025G>C p.G342A | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); catalogued as COSV101214143; called by muse, mutect2, varscan2
- GPR42 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV101497386; called by muse, mutect2, varscan2
- GRIP2 | c.2812G>A p.D938N (on ENST00000619221; = p.D841N on NM_001080423.4) | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99817751; called by muse, mutect2, varscan2
- GSK3B | c.683T>A p.I228N | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99955795; called by muse, mutect2, varscan2
- GTF2I | c.525G>C p.E175D | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV100260046, COSV60402402; called by muse, mutect2, varscan2
- HCN1 | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100302595, COSV57514751, COSV57516637; called by muse, mutect2, varscan2
- HCN1 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV100302597; called by muse, mutect2, varscan2
- HGF | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.997); catalogued as COSV55957890; called by muse, mutect2, varscan2
- HKDC1 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100664752, COSV100664807; called by muse, mutect2, varscan2
- HMX3 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.351); catalogued as COSV100774173; called by muse, mutect2, varscan2
- HTR3A | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1565580661, COSV100248653; called by muse, mutect2, varscan2
- HUWE1 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99470412, COSV99472524; called by muse, varscan2
- ICE1 | c.5693C>T p.S1898L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV99665885; called by muse, mutect2, varscan2
- ICE1 | c.6669G>C p.L2223F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99665886; called by muse, mutect2, varscan2
- IER5 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 34/117 reads (29%) | catalogued as COSV100849711; called by muse, mutect2, varscan2
- IFFO1 | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100351396; called by muse, mutect2, varscan2
- IGLV4-3 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs375166654; called by muse, mutect2, varscan2
- IGSF1 | c.3386C>T p.S1129F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV100812403, COSV63837396; called by muse, mutect2, varscan2
- IL17RE | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs200160526; called by muse, mutect2, varscan2
- ISX | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs184840753; called by mutect2, varscan2
- ITIH2 | c.2056C>G p.Q686E | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV100623459; called by muse, mutect2, varscan2
- JSRP1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99678130; called by muse, mutect2, varscan2
- KCNA5 | c.1582G>C p.D528H | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52904792, COSV99364250; called by muse, mutect2, varscan2
- KCNH1 | c.1310C>T p.S437L (on ENST00000271751 / NM_172362.3; = p.S410L on NM_002238.4) | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99661804; called by muse, mutect2, varscan2
- KIAA1210 | c.2372A>G p.D791G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV68181435; called by muse, mutect2
- KIR2DL1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.044); catalogued as COSV99383725; called by muse, mutect2, varscan2
- KMT2C | c.12694G>C p.E4232Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as COSV100066945; called by muse, mutect2, varscan2
- KNL1 | c.6077C>T p.S2026L (on ENST00000346991 / NM_170589.5; = p.S2000L on NM_144508.5) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100707121; called by muse, mutect2
- KNTC1 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs147259173, COSV100338857; called by muse, mutect2, varscan2
- LDHD | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100097614; called by muse, varscan2
- LGR4 | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200626048; called by muse, mutect2, varscan2
- LONP2 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as rs1282755664, COSV99589573; called by muse, mutect2, varscan2
- LRGUK | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV99604756; called by muse, mutect2, varscan2
- LRP1B | c.1676G>A p.R559H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs148591302; called by muse, mutect2, varscan2
- MAGEB10 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100775371; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.47G>C p.R16T | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100186710; called by muse, mutect2, varscan2
- MAP3K2 | c.883T>G p.L295V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs765850504, COSV100789404; called by muse, mutect2, varscan2
- MAP4K4 | c.1663G>A p.E555K (on ENST00000347699 / NM_001242559.2; = p.E524K on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.461); catalogued as rs760266370, COSV100156053; called by muse, mutect2, varscan2
- MAPKAPK3 | c.1118C>A p.S373Y | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV100781793; called by muse, mutect2
- MBD6 | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.953); catalogued as COSV100851843; called by muse, mutect2, varscan2
- MEF2D | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV100560430; called by muse, mutect2, varscan2
- METTL17 | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100068744; called by muse, mutect2, varscan2
- METTL18 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99610243; called by muse, mutect2, varscan2
- MMP17 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs762234548, COSV100861990; called by muse, mutect2, varscan2
- MOB1A | c.571C>G p.Q191E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.1); catalogued as rs1356284476, COSV101247378; called by muse, mutect2, varscan2
- MROH2B | c.3325G>A p.E1109K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.137); catalogued as rs1427712030, COSV101270924, COSV68181885, COSV68186148; called by muse, mutect2, varscan2
- MRPL48 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100057577; called by muse, mutect2, varscan2
- MUC1 | c.3517C>A p.L1173M (on ENST00000611571 / NM_001371720.1; = p.L184M on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100104149, COSV100104910; called by muse, mutect2, varscan2
- MUC17 | c.7474G>A p.E2492K | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100075302; called by muse, mutect2, varscan2
- MYO9A | c.3886G>A p.G1296S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.517); catalogued as rs772877901, COSV100614459; called by muse, mutect2, varscan2
- N4BP1 | c.710G>C p.R237T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99285633; called by muse, mutect2, varscan2
- NBN | c.1855G>T p.E619* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV55375105, COSV99620206; called by muse, mutect2, varscan2
- NEK8 | c.317T>G p.L106R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99262328; called by muse, mutect2, varscan2
- NF1 | c.4700C>G p.S1567* (on ENST00000358273 / NM_001042492.3; = p.S1546* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 22/77 reads (29%) | catalogued as CM143413, COSV62197495; called by muse, mutect2, varscan2
- NFIC | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100545689; called by muse, mutect2, varscan2
- NIM1K | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV100390538; called by muse, mutect2, varscan2
- NIT2 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as COSV101237139; called by muse, mutect2, varscan2
- NOTCH3 | c.6830C>T p.T2277I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs775596021, COSV99659086; called by muse, mutect2, varscan2
- NPHP1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100338371, COSV100338555; called by muse, mutect2, varscan2
- NT5C2 | c.1641C>A p.C547* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100583799; called by muse, mutect2, varscan2
- NTHL1 | c.731G>A p.R244K (on ENST00000219066; = p.R236K on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99526538; called by muse, mutect2, varscan2
- NUDC | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1178114606, COSV100264672; called by muse, mutect2, varscan2
- OBSCN | c.16157C>G p.S5386C | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99484938; called by muse, mutect2, varscan2
- OR5K1 | c.512C>A p.S171* | Nonsense Mutation (SNP) | VAF 30/105 reads (29%) | catalogued as rs199803370, COSV100221046; called by muse, mutect2, varscan2
- ORC6 | c.543G>T p.K181N | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99530989; called by muse, mutect2, varscan2
- PAX2 | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100695466; called by muse, mutect2, varscan2
- PCDH11X | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as rs1166071058, COSV100012203, COSV100015731; called by muse, mutect2, varscan2
- PCDHGB7 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV99548107; called by muse, mutect2, varscan2
- PCNX1 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV99457476; called by muse, mutect2, varscan2
- PCSK5 | c.4387G>A p.E1463K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV101377734; called by muse, mutect2, varscan2
- PDCL3 | c.572G>A p.R191K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV99959684, COSV99959735; called by muse, mutect2, varscan2
- PDE4D | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.158); catalogued as COSV101550554; called by muse, mutect2, varscan2
- PDXDC1 | c.1115A>G p.K372R | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs1466443321, COSV100363471; called by muse, mutect2, varscan2
- PEG3 | c.4084G>A p.E1362K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as rs1260704543, COSV99690631; called by muse, mutect2, varscan2
- PEG3 | c.2780C>T p.S927L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1339198889, COSV99063492, COSV99690633; called by muse, mutect2, varscan2
- PHF20L1 | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55199037; called by muse, mutect2
- PLEKHH2 | c.1434G>A p.M478I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV99175174; called by muse, mutect2, varscan2
- PLEKHO1 | c.386C>G p.S129C | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV99215448; called by muse, mutect2
- PLPP3 | c.834C>G p.F278L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100984829; called by muse, mutect2, varscan2
- PLXNA3 | c.387C>G p.F129L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV100860282, COSV63754890; called by muse, mutect2, varscan2
- PMFBP1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.299); catalogued as COSV99401593; called by muse, mutect2, varscan2
- PRKACB | c.417C>T p.F139= | Splice Region (SNP) | VAF 21/102 reads (21%) | catalogued as COSV100854011; called by muse, mutect2, varscan2
- PROS1 | c.1706C>T p.S569F | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.972); catalogued as COSV101260887; called by muse, mutect2, varscan2
- PRRC2C | c.4735G>A p.G1579S (on ENST00000367742; = p.G1577S on NM_015172.4) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); catalogued as COSV100146190; called by muse, mutect2, varscan2
- PYGO1 | c.727C>G p.Q243E | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as rs374943202; called by muse, mutect2, varscan2
- RBPMS | c.110C>A p.P37H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99824606; called by muse, mutect2, varscan2
- RCOR3 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.429); catalogued as COSV100879722; called by muse, mutect2, varscan2
- RESF1 | c.4427C>G p.S1476C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100440673; called by muse, mutect2, varscan2
- REST | c.1501G>C p.E501Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as COSV100471385; called by muse, mutect2, varscan2
- RFX3 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100175989; called by muse, mutect2, varscan2
- RMDN3 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.151); catalogued as COSV99540147; called by muse, varscan2
- RNF17 | c.2889G>C p.W963C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99694543; called by muse, mutect2, varscan2
- RPAP1 | c.3139C>G p.Q1047E | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100427381; called by muse, mutect2, varscan2
- RRM2 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as rs1315770871, COSV100459869; called by muse, mutect2, varscan2
- RXRA | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100709390; called by muse, mutect2, varscan2
- SCAF11 | c.3820C>G p.Q1274E | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101014717; called by muse, mutect2, varscan2
- SERTAD4 | c.405G>C p.L135F | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100882678, COSV65399082; called by muse, mutect2, varscan2
- SIAE | c.207G>A p.M69I | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV99704212; called by muse, mutect2, varscan2
- SIGLEC6 | c.973C>G p.L325V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.733); catalogued as COSV100585751; called by muse, mutect2, varscan2
- SLC27A1 | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772534830, COSV53097378; called by muse, mutect2, varscan2
- SLC36A3 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV100077939; called by muse, mutect2, varscan2
- SLC39A4 | c.1288G>A p.D430N (on ENST00000301305 / NM_001374839.1; = p.D405N on NM_017767.3) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV52779282, COSV99433798; called by muse, mutect2, varscan2
- SMAD3 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV59286689; called by muse, mutect2, varscan2
- SOGA3 | c.1639G>T p.D547Y | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100846730, COSV100847091; called by muse, mutect2, varscan2
- SON | c.2288C>T p.S763F | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV99280070; called by muse, mutect2, varscan2
- SPEM1 | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100081310; called by muse, mutect2, varscan2
- SPHKAP | c.3506G>A p.R1169Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs146340069, COSV100764692; called by muse, varscan2
- SPINT1 | c.1004G>A p.C335Y (on ENST00000344051 / NM_181642.3; = p.C319Y on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100689251; called by muse, mutect2, varscan2
- SPTBN4 | c.3013G>A p.E1005K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV100152262; called by muse, mutect2, varscan2
- SRCAP | c.9413G>A p.R3138H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs768891825, COSV52668601; called by muse, mutect2, varscan2
- ST20 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV99358366; called by muse, mutect2, varscan2
- STAT3 | c.1940A>T p.N647I | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.29); catalogued as rs770986654, COSV52882818; called by muse, mutect2, varscan2
- STK17A | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as COSV60048015; called by muse, mutect2, varscan2
- STK24 | c.1254C>G p.I418M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as COSV100925037; called by muse, mutect2, varscan2
- STK32C | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745972251, COSV100063517; called by muse, mutect2, varscan2
- TAF1C | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as COSV100499817; called by muse, mutect2, varscan2
- TAF5 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.839); catalogued as COSV100674771; called by muse, mutect2, varscan2
- TBCK | c.1987C>T p.L663F (on ENST00000273980 / NM_001163436.4; = p.L600F on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99913265; called by muse, varscan2
- TCP1 | c.396C>G p.I132M | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.706); catalogued as COSV100365093; called by muse, mutect2, varscan2
- TCP11L2 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as rs375276250; called by muse, mutect2, varscan2
- TENM3 | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV101305504; called by muse, mutect2, varscan2
- TESPA1 | c.478G>A p.D160N (on ENST00000316577 / NM_001098815.3; = p.D22N on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100345708; called by muse, mutect2, varscan2
- TFAP2A | c.967C>T p.L323F (on ENST00000482890; = p.L315F on NM_001032280.3) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV60233334; called by muse, mutect2, varscan2
- TFRC | c.2249C>T p.S750F | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV100786632; called by muse, mutect2, varscan2
- TGS1 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.338); catalogued as rs1381876198, COSV99485612, COSV99485818; called by muse, mutect2, varscan2
- TLE4 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.13); catalogued as COSV54634334, COSV99513361; called by muse, mutect2, varscan2
- TLN2 | c.4864C>G p.L1622V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100170223; called by muse, mutect2, varscan2
- TMCO4 | c.1702G>A p.G568R | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs745651024, COSV99230515; called by muse, mutect2, varscan2
- TMEM209 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV61022337; called by muse, mutect2, varscan2
- TMEM245 | c.1751G>C p.G584A | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.343); catalogued as rs1426228182, COSV101002476; called by muse, mutect2, varscan2
- TRAFD1 | c.1374G>A p.M458I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs775316340, COSV99987017; called by muse, mutect2
- TRIM69 | c.1465G>C p.E489Q (on ENST00000329464 / NM_182985.5; = p.E330Q on NM_080745.5) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.846); catalogued as COSV100274435; called by muse, mutect2, varscan2
- TRIM9 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100032304; called by mutect2, varscan2
- TSG101 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99324304; called by muse, mutect2, varscan2
- TTC39A | c.1573G>A p.E525K (on ENST00000447632 / NM_001297665.1; = p.E490K on NM_001080494.3) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs746175223, COSV99397163; called by muse, mutect2, varscan2
- TTC9C | c.479G>C p.R160T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs910189984, COSV99584779; called by muse, mutect2, varscan2
- TTF1 | c.731G>T p.R244I | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100524884; called by muse, mutect2, varscan2
- TTN | c.91084A>C p.I30362L (on ENST00000591111; = p.I22938L on NM_003319.4) | Missense Mutation (SNP) | VAF 20/44 reads (45%) | PolyPhen benign (0.127); catalogued as COSV100632838; called by muse, mutect2, varscan2
- TULP2 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99668126; called by muse, mutect2, varscan2
- TXLNG | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); catalogued as COSV99061403; called by muse, mutect2, varscan2
- UAP1 | c.676C>G p.L226V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV99618128; called by muse, mutect2, varscan2
- UBAC1 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as COSV100873830; called by muse, mutect2, varscan2
- UBXN2A | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753336862, COSV100465334, COSV58336485; called by muse, mutect2, varscan2
- ULBP1 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV99998317; called by muse, mutect2, varscan2
- UNC13A | c.1453C>G p.L485V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV99409747; called by muse, mutect2, varscan2
- UPF3A | c.1079G>A p.R360K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.15); catalogued as COSV100677748; called by muse, mutect2, varscan2
- USP8 | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.43); catalogued as COSV100209338; called by muse, mutect2, varscan2
- VCAM1 | c.2036G>A p.R679K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.793); catalogued as COSV99658972; called by muse, mutect2, varscan2
- VPS13B | c.6420G>T p.Q2140H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CD031491, COSV100663857; called by muse, mutect2, varscan2
- WDR17 | c.2992G>C p.E998Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.417); catalogued as COSV99708370; called by muse, varscan2
- WDR44 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99562004; called by muse, mutect2, varscan2
- WDTC1 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100089625, COSV60089410; called by muse, mutect2, varscan2
- XPC | c.1204G>C p.D402H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV99542712; called by muse, mutect2, varscan2
- XPR1 | c.1625G>A p.G542E | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV100851530; called by muse, mutect2, varscan2
- XRCC2 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.084); catalogued as rs730882047, COSV100831711; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XRCC6 | c.1366C>G p.P456A | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.018); catalogued as COSV100777931; called by muse, mutect2, varscan2
- ZDBF2 | c.6719C>G p.S2240C | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100985620, COSV65630758; called by muse, mutect2, varscan2
- ZFP69 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.179); catalogued as COSV101018406; called by muse, mutect2, varscan2
- ZGRF1 | c.4548G>C p.L1516F | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100349352, COSV58342918; called by muse, mutect2, varscan2
- ZMYM3 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100078450; called by muse, mutect2, varscan2
- ZNF260 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV101591073; called by muse, mutect2, varscan2
- ZNF462 | c.1515G>C p.Q505H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV52950372, COSV99473506; called by muse, mutect2, varscan2
- ZNF81 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 24/106 reads (23%) | catalogued as COSV100096269; called by muse, mutect2, varscan2
- ZNF85 | c.724T>A p.S242T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.194); catalogued as COSV100060179, COSV60217234; called by muse, mutect2, varscan2
- CELSR3 | c.4626del p.F1543Sfs*16 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | called by mutect2, pindel, varscan2
- MUC2 | c.2944C>T p.P982S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2
- SCRT1 | c.975_980delinsC p.A326Lfs*129 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by pindel, varscan2*
- TBC1D12 | c.1915del p.E639Kfs*26 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | called by mutect2, pindel, varscan2
- ZNF250 | c.367_368dup p.T124Kfs*11 | Frame Shift Ins (INS) | VAF 5/25 reads (20%) | called by mutect2, pindel
- AADACL4 | c.439C>T p.L147= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100879512; called by muse, mutect2, varscan2
- AAR2 | c.642G>A p.Q214= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs879221823, COSV100299450; called by muse, mutect2, varscan2
- ABCA1 | c.2097G>T p.L699= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV66072359; called by muse, mutect2, varscan2
- ABCA13 | c.11868C>G p.V3956= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV101447260; called by muse, mutect2, varscan2
- AC007040.2 | c.318G>A p.V106= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99721603; called by muse, mutect2, varscan2
- ACER2 | c.654C>T p.I218= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV100575821, COSV100575892; called by muse, mutect2, varscan2
- AGAP3 | c.108G>A p.E36= (on ENST00000622464; = p.E72= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99880415; called by muse, mutect2
- AMPD2 | c.27C>T p.G9= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs141792341, COSV99858176; called by muse, mutect2
- APPL1 | c.609C>T p.Y203= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs917922488, COSV99898083; called by muse, mutect2, varscan2
- ARHGAP35 | c.2058G>T p.L686= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV101351815; called by muse, mutect2, varscan2
- ARNT | c.627C>T p.L209= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV100591416; called by muse, mutect2, varscan2
- ASB6 | c.156C>T p.L52= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs763933016, COSV99475866; called by muse, mutect2
- ATP10D | c.3285C>G p.L1095= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV99906239; called by muse, mutect2, varscan2
- BTNL8 | c.15C>G p.L5= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99180593; called by muse, mutect2, varscan2
- C2orf16 | c.5742G>A p.E1914= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV100821074; called by muse, mutect2, varscan2
- CALB1 | c.72C>T p.D24= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV55367832; called by muse, mutect2, varscan2
- CCDC180 | c.4620G>A p.Q1540= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV100827373; called by muse, mutect2, varscan2
- CCT8L2 | c.969C>T p.I323= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100743182; called by muse, mutect2, varscan2
- CD99L2 | c.108G>A p.V36= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100306637; called by muse, mutect2, varscan2
- CECR2 | c.825C>T p.L275= (on ENST00000342247 / NM_001290047.2; = p.L112= on NM_001290046.1) | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99379249; called by muse, mutect2, varscan2
- CFAP221 | c.2511G>C p.L837= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV99733237; called by muse, mutect2, varscan2
- CFAP54 | c.7827C>T p.I2609= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV61575990; called by muse, mutect2, varscan2
- CHGA | c.108C>T p.I36= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs376854650; called by muse, mutect2, varscan2
- CHST4 | c.573G>A p.L191= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100632967; called by muse, mutect2, varscan2
- CLPX | c.1620G>A p.L540= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2
- CYP11B1 | c.273G>C p.V91= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV52825993, COSV99455795; called by muse, mutect2, varscan2
- DERL3 | c.432C>T p.F144= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs755146987, COSV99320377; called by muse, mutect2, varscan2
- DNAH11 | c.12111C>G p.L4037= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100181148; called by muse, mutect2, varscan2
- DNAH8 | c.6351G>T p.T2117= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100547331; called by muse, mutect2, varscan2
- DNAH9 | c.4167G>A p.L1389= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99308462; called by muse, mutect2, varscan2
- DNAH9 | c.9693G>A p.E3231= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99308465; called by muse, mutect2
- DNM1 | c.648C>G p.A216= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100360429; called by muse, mutect2, varscan2
- DOLK | c.147C>T p.L49= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV101001512, COSV65364433; called by muse, mutect2, varscan2
- DZIP1L | c.1221C>T p.L407= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs754970653, COSV59519639, COSV59523129; called by muse, mutect2, varscan2
- ELAVL3 | c.300C>T p.L100= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs764675042, COSV100820883; called by muse, mutect2, varscan2
- ERVW-1 | c.1323C>T p.L441= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV101423878; called by muse, mutect2, varscan2
- FAT1 | c.12078C>T p.G4026= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV71672656; called by muse, mutect2, varscan2
- FAT4 | c.8154C>T p.F2718= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100630419; called by muse, mutect2, varscan2
- FIGN | c.924G>A p.L308= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100293018; called by muse, mutect2, varscan2
- FOXN1 | c.840C>T p.I280= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV99881577; called by muse, mutect2, varscan2
- FUBP1 | c.570C>T p.I190= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV99629680; called by muse, mutect2, varscan2
- GABRG1 | c.1005C>T p.L335= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99778840; called by muse, mutect2, varscan2
- GLRA3 | c.279G>A p.V93= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99928273; called by muse, mutect2
- HCN4 | c.1254C>T p.I418= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs373794941, COSV56082203; ClinVar: likely benign; called by muse, mutect2, varscan2
- HECTD2 | c.1198C>T p.L400= | Silent (SNP) | VAF 25/141 reads (18%) | catalogued as rs1186819717, COSV53222513, COSV99979036; called by muse, mutect2, varscan2
- ISX | c.414G>A p.R138= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs372007711; called by mutect2, varscan2
- KIAA1549L | c.2433G>A p.T811= (on ENST00000321505; = p.T1108= on NM_012194.3) | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs1394089967, COSV99684606; called by muse, mutect2, varscan2
- KIT | c.1911C>T p.L637= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99855474; called by muse, mutect2, varscan2
- LAMB2 | c.234C>T p.I78= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs201179067, COSV100565537; called by muse, mutect2, varscan2
- MBIP | c.51G>T p.L17= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100576847; called by muse, mutect2
- MTDH | c.1626G>A p.E542= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV100292822; called by muse, mutect2, varscan2
- MYBBP1A | c.1914G>A p.K638= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as rs376866252; called by muse, mutect2, varscan2
- MYO1F | c.2751T>C p.D917= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs568316480, COSV100597134; called by muse, mutect2, varscan2
- NCOA2 | c.4362G>A p.K1454= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV99145061; called by muse, mutect2, varscan2
- NDOR1 | c.1431G>A p.Q477= (on ENST00000371521 / NM_001144026.3; = p.Q470= on NM_014434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV100789100; called by muse, mutect2, varscan2
- NIPAL4 | c.399C>T p.G133= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100357338; called by muse, mutect2, varscan2
- NKAIN4 | c.465G>C p.L155= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as COSV100941710; called by muse, mutect2, varscan2
- NMUR2 | c.645C>T p.F215= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV54916824; called by muse, mutect2, varscan2
- NOTCH3 | c.2316C>G p.L772= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99659087; called by muse, mutect2
- NUDT11 | c.408C>T p.H136= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as rs782024387, COSV101047115; called by muse, mutect2, varscan2
- OR11H1 | c.432C>G p.L144= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs1235632803, COSV99422034; called by muse, mutect2, varscan2
- OR1J1 | c.876G>A p.L292= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV52238826, COSV99403272; called by muse, mutect2, varscan2
- OR2L8 | c.702G>A p.K234= | Silent (SNP) | VAF 34/144 reads (24%) | catalogued as COSV100594339; called by muse, mutect2, varscan2
- OR5H14 | c.693C>G p.V231= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV71193603; called by muse, mutect2, varscan2
- OR8J1 | c.468T>G p.A156= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100275240; called by muse, mutect2, varscan2
- ORMDL2 | c.411G>A p.P137= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs776670385, COSV54478801; called by muse, mutect2, varscan2
- PAK3 | c.1134G>A p.Q378= (on ENST00000262836 / NM_001324328.2; = p.Q363= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV53272110, COSV99035274, COSV99458471; called by muse, mutect2, varscan2
- PHKG1 | c.1104A>C p.A368= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV99305468; called by muse, mutect2, varscan2
- PHRF1 | c.345C>T p.F115= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV52752584; called by muse, mutect2, varscan2
- PLXNA3 | c.954C>T p.F318= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV100860285; called by muse, mutect2, varscan2
- POMT2 | c.945C>T p.F315= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV99836734; called by muse, mutect2, varscan2
- POU5F2 | c.342G>A p.P114= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs756450444, COSV67937825; called by muse, mutect2, varscan2
- PSMD7 | c.21G>A p.Q7= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV99542855; called by muse, mutect2, varscan2
- PWWP3B | c.1023G>A p.Q341= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100531671; called by muse, mutect2
- QSOX1 | c.1374G>A p.Q458= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV100852966, COSV62580864; called by muse, mutect2, varscan2
- RALGAPA1 | c.4731G>A p.E1577= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99356315; called by muse, mutect2, varscan2
- RBAK | c.1305G>A p.G435= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100806792; called by muse, mutect2, varscan2
- REST | c.1200G>A p.K400= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100470855; called by muse, mutect2, varscan2
- SIDT2 | c.1287C>G p.L429= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV99638525; called by muse, mutect2, varscan2
- SLC17A9 | c.979C>T p.L327= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100948015; called by muse, mutect2
- SLC25A18 | c.36C>T p.L12= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100541239; called by muse, mutect2, varscan2
- SPEN | c.69C>T p.I23= | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as COSV100402931; called by muse, mutect2, varscan2
- TAF6L | c.975C>T p.V325= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99585493; called by muse, mutect2, varscan2
- TERF2IP | c.627C>G p.L209= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100094595; called by muse, mutect2, varscan2
- TMC1 | c.1581G>A p.L527= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV99920648; called by muse, mutect2, varscan2
- TMPRSS11E | c.243G>A p.Q81= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100542137, COSV100542559; called by muse, mutect2, varscan2
- TOP1 | c.1704C>G p.L568= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV63694814; called by muse, mutect2
- TRMT61B | c.1433G>A p.*478= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV100066841; called by muse, mutect2, varscan2
- TRRAP | c.1362C>T p.L454= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100723095; called by muse, mutect2, varscan2
- TSR1 | c.2193G>C p.L731= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100027243, COSV100027244; called by muse, mutect2, varscan2
- USHBP1 | c.376C>T p.L126= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as rs371881438; called by muse, mutect2, varscan2
- VWA5A | c.954G>A p.K318= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs759407355, COSV63707409, COSV63707433; called by muse, mutect2, varscan2
- WFS1 | c.1335G>A p.L445= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV56991353, COSV99901660; called by muse, mutect2, varscan2
- CSNK1G2 | c.-266+12549C>A | Intron (SNP) | VAF 7/26 reads (27%) | catalogued as rs1003754101; called by muse, mutect2
- MC3R | c.-22C>G | 5'UTR (SNP) | VAF 7/25 reads (28%) | catalogued as rs376616332, COSV99710891; called by muse, mutect2, varscan2
- PODNL1 | c.-15G>A | 5'UTR (SNP) | VAF 17/72 reads (24%) | catalogued as COSV99583098; called by muse, mutect2, varscan2
- PSG5 | c.430+1349C>G | Intron (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100743212; called by muse, mutect2
- RPL13A | c.88+95G>A | Intron (SNP) | VAF 23/114 reads (20%) | catalogued as COSV52618749, COSV99201373; called by muse, mutect2, varscan2
- SPTBN4 | c.5915+70G>A | Intron (SNP) | VAF 8/23 reads (35%) | catalogued as rs374217622; called by muse, varscan2
